CCDI case PBCIGV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/12e9a785-fc6f-4c85-aec8-e94100bcb508

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.3 years (5,594 days).

Biospecimens (3 samples)
- Sample 0DSI7L: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSI8C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSI9I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
